Somatic mutation profile of tumor specimen C3L-03628-01 (aliquot CPT0198700008) from CPTAC case C3L-03628, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.2 years (25,282 days).
Specimen C3L-03628-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7255c1f1-675c-4398-9816-3bebfd3be1bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03628-31 (Blood Derived Normal), aliquot CPT0198740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9545dc32-c034-4b02-970e-ec61ed0a4944

The open-access MAF lists 41 somatic variants for this specimen: 26 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 13, Nonsense Mutation 4, RNA 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 61/514 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.695T>G p.I232S | Missense Mutation (SNP) | VAF 50/600 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs587781589, CM103212, COSV52661257, COSV52760307, COSV52829354; ClinVar: likely pathogenic; called by muse, mutect2
- ARR3 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs371232872; called by muse, mutect2
- ATP2A1 | c.2644C>T p.H882Y | Missense Mutation (SNP) | VAF 48/1165 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as rs756859416; called by muse, mutect2
- CDH12 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV66401295; called by muse, mutect2
- DYSF | c.1097G>A p.S366N | Missense Mutation (SNP) | VAF 40/617 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV50301205; called by muse, mutect2
- IRAK1 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1557128414; called by muse, mutect2
- KRT9 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 25/670 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs761374587, COSV55851792; called by muse, mutect2
- L1CAM | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 28/365 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs200605257, COSV62828942; called by muse, mutect2
- LUZP2 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as rs1370147229, COSV61204414; called by muse, mutect2
- MAP1B | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 29/525 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200457818, COSV57096970; called by muse, mutect2
- OR52J3 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs759986415, COSV66746819; called by muse, mutect2
- OR8H3 | c.781A>C p.K261Q | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.987); catalogued as COSV57907548; called by muse, mutect2
- PHKB | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 36/618 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs369997789, COSV54534896; called by muse, mutect2
- ACAA1 | c.321G>A p.L107= | Splice Region (SNP) | VAF 22/317 reads (7%) | called by muse, mutect2
- ADD2 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 19/279 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.122); called by muse, mutect2
- ANPEP | c.2739T>G p.Y913* | Nonsense Mutation (SNP) | VAF 30/432 reads (7%) | called by muse, mutect2
- CD79B | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 48/924 reads (5%) | called by muse, mutect2
- DAPK1 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2
- ILRUN | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RBFOX1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 30/656 reads (5%) | called by muse, mutect2
- SUPV3L1 | c.510T>G p.F170L | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- TAF1L | c.1610A>G p.E537G | Missense Mutation (SNP) | VAF 34/422 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- TEX15 | c.3020C>T p.A1007V (on ENST00000256246; = p.A1390V on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- ULK1 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF780B | c.419A>G p.N140S | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.009); called by muse, mutect2
- ASPM | c.5314C>T p.L1772= | Silent (SNP) | VAF 17/348 reads (5%) | called by muse, mutect2
- B3GAT1 | c.477C>T p.R159= | Silent (SNP) | VAF 32/479 reads (7%) | catalogued as rs1247871633, COSV56998007; called by muse, mutect2
- CUX2 | c.717C>T p.V239= | Silent (SNP) | VAF 26/435 reads (6%) | called by muse, mutect2
- EBF2 | c.1722G>A p.P574= | Silent (SNP) | VAF 18/360 reads (5%) | catalogued as rs773515338, COSV68780534; called by muse, mutect2
- FTSJ1 | c.186G>A p.K62= | Silent (SNP) | VAF 52/641 reads (8%) | called by muse, mutect2
- HNRNPCL2 | c.429G>A p.S143= | Silent (SNP) | VAF 32/281 reads (11%) | catalogued as rs767487977, COSV60403518; called by muse, mutect2, varscan2
- KCNMB2 | c.237C>T p.T79= | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as rs767171556; called by muse, mutect2
- KRT72 | c.327G>A p.P109= | Silent (SNP) | VAF 26/350 reads (7%) | catalogued as rs777799663, COSV99537223; called by muse, mutect2
- LRRC28 | c.669G>C p.L223= | Silent (SNP) | VAF 15/312 reads (5%) | called by muse, mutect2
- PRXL2B | c.579C>T p.S193= (on ENST00000444521; = p.S145= on NM_152371.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/273 reads (7%) | catalogued as rs536749188; called by muse, mutect2
- SCN4A | c.2586C>T p.D862= | Silent (SNP) | VAF 32/425 reads (8%) | catalogued as rs756161095, COSV101438331; ClinVar: likely benign; called by muse, mutect2
- SORCS2 | c.1290C>T p.D430= | Silent (SNP) | VAF 28/394 reads (7%) | catalogued as rs773780208; called by muse, mutect2
- ZNF804A | c.21C>T p.V7= | Silent (SNP) | VAF 30/392 reads (8%) | catalogued as COSV56463713; called by muse, mutect2
- ARL5A | c.339+1798G>T | Intron (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- HSPA7 | n.318C>T | RNA (SNP) | VAF 54/842 reads (6%) | catalogued as rs753568412; called by muse, mutect2
